Gene-level copy-number profile of tumor specimen TCGA-57-1992-01A from TCGA case TCGA-57-1992, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3.
Specimen TCGA-57-1992-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8b66a23d-b6c1-46bc-9ac2-eee368762059.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-57-1992-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ffdae0b9-1c74-43fa-95aa-6e4c9430036f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 27,179; copy number 2: 27,472; copy number 3: 5,019; copy number 4: 72; copy number 5: 70; copy number 9: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-57-1992-01A-01D-0648-01): tumor purity 0.87, ploidy 1.65, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:174,302,944–174,378,005, 2 genes, copy number 5: ANAPC15P2, AC069218.1.
- chr3:174,631,823–174,632,064, 1 gene, copy number 5: RN7SKP40.
- chr8:46,028,804–47,202,897, 30 genes, copy number 5: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1.
- chr12:46,004,038–46,004,685, 1 gene, copy number 5: AC084878.1.
- chr12:87,746,567–89,709,300, 36 genes, copy number 5 (within-gene range 1–5): AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1.
- chr21:34,787,801–36,004,667, 1 gene, copy number 9 (within-gene range 4–9): RUNX1.
- chr21:35,472,095–36,007,838, 7 genes, copy number 9: RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2, LINC01436.

Autosomal genes at a single copy (total copy number 1): 24,761. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
